Somatic mutation profile of tumor specimen TCGA-14-0817-01A (aliquot TCGA-14-0817-01A-01D-1492-08) from TCGA case TCGA-14-0817, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,425 days).
Specimen TCGA-14-0817-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6f30831-3756-4b90-88bd-1ad00ac71b19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0817-10A (Blood Derived Normal), aliquot TCGA-14-0817-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d7c809-48fa-45a0-970b-eae2a4d91d5c

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 91/245 reads (37%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- ABCB1 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200280095, COSV55957617; called by muse, mutect2, varscan2
- ADGRV1 | c.4708A>G p.N1570D | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs537211169, COSV67991024; called by muse, mutect2, varscan2
- APOBEC3H | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1254444554, COSV62378961; called by muse, mutect2, varscan2
- ARHGEF16 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs201826500; called by muse, mutect2, varscan2
- ASTL | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs568621983, COSV100668435, COSV60904872; called by muse, mutect2, varscan2
- CALN1 | c.277G>T p.D93Y (on ENST00000329008 / NM_001017440.3; = p.D135Y on NM_031468.4) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61142880, COSV61151370; called by muse, mutect2, varscan2
- CENPE | c.4087G>T p.V1363F | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54385487; called by muse, mutect2, varscan2
- CENPM | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV53245512; called by muse, mutect2
- CNGA1 | c.1967C>A p.T656N | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV62055686; called by muse, mutect2, varscan2
- CSPG5 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1475892335, COSV53132448; called by muse, mutect2, varscan2
- ENOX2 | c.1708A>C p.T570P (on ENST00000338144 / NM_001382520.1; = p.T541P on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57655547; called by muse, mutect2, varscan2
- EPB41L3 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1050259718, COSV59445208, COSV59460193; called by muse, mutect2, varscan2
- ESPNL | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as rs1339572829, COSV58036666; called by muse, mutect2, varscan2
- EXD2 | c.1156+1G>T p.X386_splice (on ENST00000312994 / NM_001193362.1; = p.X261_splice on NM_018199.3) | Splice Site (SNP) | VAF 80/170 reads (47%) | catalogued as COSV57281045; called by muse, mutect2, varscan2
- FAM214B | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.722); catalogued as COSV59717032; called by muse, mutect2, varscan2
- FLG | c.5096G>A p.R1699H | Missense Mutation (SNP) | VAF 324/787 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs778016068, COSV64240153; called by muse, mutect2, varscan2
- GLUD2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs201021827, COSV60152595; called by muse, mutect2, varscan2
- GOLGA6B | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.908); catalogued as COSV69770105, COSV69770109; called by muse, mutect2, varscan2
- HCRTR1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 164/590 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200094994, COSV65485076; called by muse, mutect2, varscan2
- KCNH1 | c.1496C>T p.T499M (on ENST00000271751 / NM_172362.3; = p.T472M on NM_002238.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs942768469, COSV55092957; called by muse, mutect2
- L1CAM | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1172761444, COSV62829158; called by muse, mutect2, varscan2
- LCOR | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 104/156 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758284781, COSV53717379; called by muse, mutect2, varscan2
- LMOD2 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV71755757; called by muse, mutect2, varscan2
- LRRC4C | c.1899C>A p.D633E | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as COSV53431223, COSV53432557; called by muse, mutect2, varscan2
- MDK | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs926649994, COSV58993673; called by muse, mutect2, varscan2
- MEP1A | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV57921586; called by muse, mutect2, varscan2
- MYORG | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52627876; called by muse, mutect2, varscan2
- NPY5R | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV58452979; called by muse, mutect2
- NR1H4 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs766734563, COSV51854781; called by muse, mutect2, varscan2
- NUP153 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206797912, COSV50456193; called by muse, mutect2, varscan2
- OR2A12 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770301708, COSV68821103; called by muse, mutect2, varscan2
- PEX1 | c.3305G>T p.C1102F | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV50406204; called by muse, mutect2, varscan2
- PHEX | c.1364A>T p.E455V | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV65077411; called by muse, mutect2, varscan2
- PHYHIP | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV58689080; called by muse, mutect2, varscan2
- PKLR | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV61361920; called by muse, mutect2, varscan2
- PLCL1 | c.3086G>A p.W1029* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV70852554; called by muse, mutect2, varscan2
- PSRC1 | c.994G>A p.V332I (on ENST00000409138 / NM_001363309.1; = p.V302I on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV64021500; called by muse, mutect2, varscan2
- RBM19 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs376588204; called by muse, mutect2
- SCN7A | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs766963704, COSV69269732; called by muse, mutect2, varscan2
- SLC22A2 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs763402163, COSV65267115; called by muse, mutect2, varscan2
- SLC5A12 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 102/352 reads (29%) | catalogued as rs760914360, COSV54823292; called by muse, mutect2, varscan2
- SLC7A8 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758825641, COSV100328377, COSV57555088; called by muse, mutect2, varscan2
- SLC9A3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs375784344; called by muse, mutect2, varscan2
- SUPT3H | c.650G>A p.C217Y (on ENST00000371460 / NM_181356.3; = p.C206Y on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV60945305; called by muse, mutect2, varscan2
- SYNE1 | c.3850C>T p.R1284W (on ENST00000367255 / NM_182961.4; = p.R1291W on NM_033071.3) | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs140780725; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYT6 | c.464G>A p.R155H (on ENST00000610222 / NM_001366225.1; = p.R70H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs138691067; called by muse, mutect2, varscan2
- TRPV5 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.121); catalogued as rs200067461, COSV54687034; called by muse, mutect2, varscan2
- TTN | c.27311C>T p.T9104M (on ENST00000591111; = p.T8177M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/188 reads (43%) | PolyPhen benign (0.051); catalogued as rs375209383; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WFDC3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 17/288 reads (6%) | catalogued as rs1171816324, COSV54785793; called by muse, mutect2
- ZBP1 | c.157A>C p.K53Q | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV59063403; called by muse, mutect2, varscan2
- SLITRK2 | c.56_59del p.T19Rfs*23 | Frame Shift Del (DEL) | VAF 38/89 reads (43%) | called by pindel, varscan2
- TP53 | c.581_585del p.L194Pfs*13 | Frame Shift Del (DEL) | VAF 75/94 reads (80%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.4845G>A p.S1615= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1277026731, COSV55235100; called by muse, mutect2, varscan2
- CAPN3 | c.1818G>A p.S606= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs28364528, CM1513307; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DSG3 | c.276C>A p.I92= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV57126509, COSV99934744; called by muse, mutect2, varscan2
- GRM1 | c.2583C>T p.G861= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs148042148; called by muse, mutect2, varscan2
- HTR1E | c.27G>A p.E9= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV59509343, COSV59510342; called by muse, mutect2, varscan2
- INS | c.333G>A p.*111= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV51747805; called by muse, varscan2
- KBTBD12 | c.1635C>T p.T545= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV59680723; called by muse, mutect2, varscan2
- MYH2 | c.705C>T p.N235= | Silent (SNP) | VAF 152/196 reads (78%) | catalogued as rs201018335, COSV55434048; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPTX2 | c.711C>T p.Y237= | Silent (SNP) | VAF 121/504 reads (24%) | catalogued as rs573416055, COSV55717304, COSV55717885; called by muse, mutect2, varscan2
- PZP | c.1158C>T p.D386= | Silent (SNP) | VAF 60/172 reads (35%) | catalogued as rs752019492, COSV54362232; called by muse, mutect2, varscan2
- RIPK4 | c.2037C>T p.N679= (on ENST00000352483; = p.N631= on NM_020639.3) | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs781171886, COSV60186148; called by muse, mutect2, varscan2
- SLC9A3 | c.378C>T p.D126= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs768111524; called by muse, mutect2
- SLCO5A1 | c.684C>T p.N228= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs765328168, COSV52660294; called by muse, mutect2, varscan2
- SPTB | c.1704G>A p.Q568= | Silent (SNP) | VAF 118/285 reads (41%) | catalogued as COSV67633712; called by muse, mutect2, varscan2
- TGFBR3 | c.333G>A p.V111= | Silent (SNP) | VAF 147/304 reads (48%) | catalogued as COSV53028829; called by muse, mutect2, varscan2
- SSPOP | n.8767del | RNA (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
